Gene-level copy-number profile of tumor specimen TCGA-66-2787-01A from TCGA case TCGA-66-2787, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 57.8 years (21,124 days).
Specimen TCGA-66-2787-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.455ec506-1295-49b9-bd5b-c86613f76541.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2787-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f042f01-279f-465b-8a8e-99cc9c7e700b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 206; copy number 2: 22,726; copy number 3: 13,894; copy number 4: 16,002; copy number 5: 3,292; copy number 6: 1,863; copy number 8: 1,676; copy number 9: 148; copy number 10: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2787-01A-01D-0978-01): tumor purity 0.36, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:149,547,154–149,624,752, 1 gene (within-gene range 0–5): ZNF767P.
- chr16:56,989,485–57,083,531, 2 genes (within-gene range 0–2): NLRC5, AC023825.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,984 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–150,765,792, 273 genes, copy number 6 (broad region; genes not listed).
- chr1:153,661,788–158,883,500, 262 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:160,485,030–160,828,261, 11 genes, copy number 6: SLAMF6, AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2, LY9.
- chr1:171,841,498–172,418,466, 1 gene, copy number 6 (within-gene range 4–6): DNM3.
- chr1:172,138,397–186,988,981, 278 genes, copy number 6–8 (broad region; genes not listed).
- chr1:231,626,790–232,041,272, 1 gene, copy number 5 (within-gene range 4–5): DISC1.
- chr1:231,925,834–232,897,660, 12 genes, copy number 5: DISC1-IT1, AL353052.1, AL353052.2, BX323014.1, RN7SL299P, SIPA1L2, RNU6-1211P, LINC01745, LINC01744, MAP10, RNU1-74P, AL122003.2.
- chr2:49,918,503–88,825,207, 688 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:88,812,370–88,812,454, 1 gene, copy number 5: MIR4436A.
- chr2:182,716,041–190,692,766, 95 genes, copy number 5 (broad region; genes not listed).
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 5–8 (broad region; genes not listed).
- chr4:44,622,065–44,726,588, 5 genes, copy number 10 (within-gene range 6–10): YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1.
- chr4:46,531,237–62,510,771, 215 genes, copy number 5–9 (broad region; genes not listed).
- chr4:116,714,844–136,553,739, 215 genes, copy number 5–6 (broad region; genes not listed).
- chr5:25,701,217–42,721,878, 239 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr5:42,729,138–45,895,970, 58 genes, copy number 5: AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:167,607–24,666,930, 393 genes, copy number 5 (broad region; genes not listed).
- chr7:144,048,948–149,497,817, 89 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:149,714,781–159,233,377, 201 genes, copy number 5 (broad region; genes not listed).
- chr9:27,948,078–28,670,286, 1 gene, copy number 6 (within-gene range 3–6): LINGO2.
- chr9:28,539,735–31,381,490, 21 genes, copy number 6: AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243.
- chr9:35,490,111–37,358,149, 74 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:54,591,480–60,417,756, 289 genes, copy number 5 (broad region; genes not listed).
- chr12:66,023,620–67,069,162, 18 genes, copy number 5 (within-gene range 3–5): MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4.
- chr16:34,051,140–35,912,516, 94 genes, copy number 5 (broad region; genes not listed).
- chr17:11,598,470–12,215,267, 10 genes, copy number 5: DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2.
- chr17:44,004,622–83,095,122, 1,272 genes, copy number 5–6 (broad region; genes not listed).
- chr18:47,390–7,461,135, 150 genes, copy number 5 (broad region; genes not listed).
- chr18:7,741,310–7,815,730, 2 genes, copy number 5: AP000897.2, AP000897.1.
- chr19:94,062–921,005, 57 genes, copy number 6: OR4G3P, OR4G1P, OR4F17, WBP1LP11, OR4F8P, AC092192.1, SEPTIN14P19, CICP19, AC092299.1, AC010507.1, LINC01002, AC010507.2, RNU6-1076P, AC016588.2, PLPP2, MIER2, AC016588.1, THEG, AC010641.2, AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2, MADCAM1, AC005775.1, TPGS1, CDC34, GZMM, AC009005.1, BSG, HCN2, AC005559.1, POLRMT, AC004449.1, FGF22, RNF126, AC004156.1, FSTL3, PRSS57, RPS2P52, PALM, MISP, AC006273.1, LINC01836, PTBP1, MIR4745, PLPPR3, MIR3187, AZU1, PRTN3, ELANE, CFD, MED16, RNU6-9, R3HDM4, KISS1R.
- chr19:928,259–928,817, 1 gene, copy number 6: AC005379.1.
- chr21:10,328,411–22,098,518, 156 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 198. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
